MMRF case MMRF_1796 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3b119f1a-9f12-4629-9ee8-0a54cb69d28f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.4 years (26,822 days); ISS stage: I; Days to last known disease status: 1,080 days (3.0 years); Days to last follow up: 1,080 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 66 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 1 g/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 7.12 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 5.27 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.96 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.73 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 0.4 mg/dL.
- Day 91 (ECOG 1): Lactate Dehydrogenase 5.27 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 8.9 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 6.16 mmol/L.
- Day 162 (ECOG 1): Lactate Dehydrogenase 4.4 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 350 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.8 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 8.75 mmol/L.
- Day 261: Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.06 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 7.48 mmol/L.
- Day 331 (ECOG 1): M Protein 0.1 g/dL; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 7.81 mmol/L.
- Day 422 (ECOG 1): Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.68 mmol/L; Albumin 48 g/L; Total Protein 7.5 g/dL; Glucose 5.39 mmol/L.
- Day 534: Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.65 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 618: Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.58 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 702: Hemoglobin 7.44 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 800: Hemoglobin 7.07 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.55 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.28 mmol/L.
- Day 884: Hemoglobin 7.01 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 9.8 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.68 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.
- Day 982: Hemoglobin 7.5 mmol/L; Leukocytes 20.4 ×10⁹/L; Absolute Neutrophil 17.2 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.58 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 4.68 mmol/L.
- Day 1,080: Immunoglobulin G 4.88 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -12: Weight: 56 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1796_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1796_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
